Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0FD, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0FD-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement Anatomic Site: **Right breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **OCT**

Container: **block** Type of Procurement: **surgery** Grade: **2**

T Stage: **2** N Stage: **0** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

ICD-0-3

carcinoma, infiltrating duct, NOS 8500/3

site: breast, NOS C50.9

lw 10/21/11

lw 10/21/11		

Source: NCI Genomic Data Commons file 75a4a8c1-6a2a-4ed9-a005-b01c77ed1470 (TCGA-AN-A0FD.F124155D-6131-47F6-8320-46A41AB125D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).